Somatic mutation profile of tumor specimen ALCH-B3IV-TTP1-A (aliquot ALCH-B3IV-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3IV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.4 years (24,603 days).
Specimen ALCH-B3IV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c7bd4aa-4a43-47f3-8949-8e08ce1c6694.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3IV-NB1-A (Blood Derived Normal), aliquot ALCH-B3IV-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40149f4c-a3e1-426b-8045-74d01c773899

The open-access MAF lists 27 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, 3'UTR 3, Nonsense Mutation 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP13A2 | c.1967C>T p.S656F | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs982452930; called by muse, mutect2, varscan2
- BST2 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV53089263, COSV99392063; called by muse, mutect2
- FAT2 | c.5191C>T p.R1731* | Nonsense Mutation (SNP) | VAF 31/179 reads (17%) | catalogued as rs773531501, COSV55821035; called by muse, mutect2, varscan2
- MUC16 | c.23965A>G p.T7989A | Missense Mutation (SNP) | VAF 49/274 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.714); catalogued as rs1279553420; called by muse, mutect2, varscan2
- NCOA6 | c.5374A>G p.M1792V | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs775051225; called by muse, mutect2, varscan2
- OR2Y1 | c.847A>G p.I283V | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as COSV57137731; called by mutect2, varscan2
- PALMD | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as COSV54164336; called by muse, mutect2, varscan2
- SI | c.2515G>T p.D839Y | Missense Mutation (SNP) | VAF 46/310 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs201944977, COSV52265311, COSV52286186, COSV52301725; called by muse, mutect2, varscan2
- TBC1D4 | c.3709C>T p.L1237F | Missense Mutation (SNP) | VAF 44/724 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100884661; called by muse, mutect2
- ADAM21 | c.608G>C p.W203S | Missense Mutation (SNP) | VAF 97/373 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- AHCY | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 130/696 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CSTF3 | c.585+1G>A p.X195_splice | Splice Site (SNP) | VAF 18/130 reads (14%) | called by muse, varscan2
- EP300 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 24/556 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- FNDC3A | c.1699C>T p.P567S (on ENST00000492622 / NM_001079673.2; = p.P511S on NM_014923.5) | Missense Mutation (SNP) | VAF 44/346 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- H1-6 | c.227A>T p.D76V | Missense Mutation (SNP) | VAF 114/523 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SARM1 | c.1190T>G p.L397R | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.123); called by muse, mutect2
- TOP2A | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 29/292 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZNF648 | c.521T>A p.L174H | Missense Mutation (SNP) | VAF 87/448 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- COPB1 | c.912C>T p.R304= | Silent (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2
- MYH9 | c.1506C>T p.I502= | Silent (SNP) | VAF 32/810 reads (4%) | catalogued as rs779557497, COSV53382439; called by muse, mutect2
- NAALADL1 | c.250C>T p.L84= | Silent (SNP) | VAF 36/208 reads (17%) | called by muse, mutect2, varscan2
- NR0B1 | c.282G>A p.P94= | Silent (SNP) | VAF 30/436 reads (7%) | catalogued as COSV66763741, COSV66764402; called by muse, mutect2
- PCNX1 | c.4215T>C p.F1405= | Silent (SNP) | VAF 25/183 reads (14%) | called by muse, mutect2, varscan2
- ASB9 | c.*26A>G | 3'UTR (SNP) | VAF 28/138 reads (20%) | called by mutect2, varscan2
- LRRC18 | c.*38C>T | 3'UTR (SNP) | VAF 44/239 reads (18%) | catalogued as COSV99629348; called by muse, mutect2, varscan2
- NOL6 | c.*509A>T | 3'UTR (SNP) | VAF 43/259 reads (17%) | called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 51/251 reads (20%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
